Gene-level copy-number profile of tumor specimen ALCH-AEFK-TTP1-A from ALCHEMIST case ALCH-AEFK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.6 years (22,882 days).
Specimen ALCH-AEFK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b5a056e9-d9dd-43bb-b899-f6652c56ade8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEFK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/df2d19b2-0992-4514-acda-881846722c93

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 2,645; copy number 2: 53,351; copy number 3: 2,360; copy number 4: 10; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:33,141,871–33,143,230, 1 gene: AL662907.1.
- chr3:46,835,111–46,903,799, 2 genes: MYL3, PTH1R.
- chr4:4,844,188–4,863,936, 2 genes: LINC01396, MSX1.
- chr5:139,644,460–139,683,882, 3 genes: AC113361.1, CXXC5, CXXC5-AS1.
- chr6:35,070,871–35,071,049, 1 gene (within-gene range 0–2): AL138721.1.
- chr9:12,134–73,865, 5 genes (within-gene range 0–2): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C.
- chr9:42,183,659–42,204,988, 3 genes: SPATA31A6, AL445584.1, FAM74A7.
- chr9:93,147,040–93,148,556, 1 gene: AL390760.1.
- chr10:102,449,816–102,477,045, 3 genes: RPARP-AS1, C10orf95, MFSD13A.
- chr15:76,993,359–77,037,475, 1 gene: PSTPIP1.
- chr15:77,043,680–77,045,160, 1 gene (within-gene range 0–2): AC090181.1.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr17:183,824–191,587, 1 gene: LINC02091.
- chr19:39,825,350–39,846,379, 3 genes: DYRK1B, MIR6719, FBL.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:44,107,373–44,131,181, 1 gene, copy number 8: PWP2.

Autosomal genes at a single copy (total copy number 1): 2,615. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
